BEATAML1.0 case 2589 — Functional Genomic Landscape of Acute Myeloid Leukemia (BEATAML1.0-COHORT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems.
https://portal.gdc.cancer.gov/cases/a9f6f4c1-75ae-471d-94ff-5014c02350f1

Demographics
Sex at birth: male; Vital status: Dead.

Diagnoses (1)
1. Acute myeloid leukemia with t(6;9)(p23;q34), DEK-NUP214: ICD-O-3 morphology code: 9865/3; Tissue or organ of origin: Bone marrow; Age at diagnosis: 38.8 years (14,167 days); Progression or recurrence: yes; ELN risk classification: Adverse.

Biospecimens (2 samples)
- Sample BA3064D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
- Sample BA3064R: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Fresh.
